Somatic mutation profile of tumor specimen 7cc7f69f-99f5-4b23-a9e0-ba0dc8 (aliquot 7cc7f69f-99f5-4b23-a9e0-ba0dc8_D6) from CPTAC case 05CO003, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II.
Specimen 7cc7f69f-99f5-4b23-a9e0-ba0dc8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8bfa3ea-cf63-49fd-853f-1a5762908e99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4ecabbd2-ce60-46d1-a451-b8d106 (Blood Derived Normal), aliquot 4ecabbd2-ce60-46d1-a451-b8d106_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4d397f5-a7bb-49ed-aa40-8ffc4b95da2d

The open-access MAF lists 1,575 somatic variants for this specimen: 1,043 protein-altering or splice-affecting, 319 silent, 213 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 728, Silent 319, Frame Shift Del 207, Intron 115, 3'UTR 35, Nonsense Mutation 33, Frame Shift Ins 26, 5'UTR 24, Splice Site 21, RNA 21, In Frame Del 14, Splice Region 14.

Variants (750 of 1,575; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 44/239 reads (18%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEL | c.1785del p.V596Cfs*111 (on ENST00000673714; = p.V593Cfs*111 on NM_001807.6) | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | catalogued as rs193922638; ClinVar: likely pathogenic; called by mutect2, varscan2
- CEP290 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs1170451277, CM111855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3124C>T p.Q1042* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | catalogued as rs397508500, CM983571; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHEK2 | c.276dup p.W93Lfs*15 | Frame Shift Ins (INS) | VAF 34/180 reads (19%) | catalogued as rs876661156; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CUL4B | c.923dup p.L308Ffs*5 | Frame Shift Ins (INS) | VAF 15/54 reads (28%) | catalogued as rs1556216330; ClinVar: pathogenic; called by mutect2, varscan2
- DMD | c.6986del p.K2329Sfs*9 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs398124040, CD972168; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FOXE1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894111, CM063998; ClinVar: pathogenic; called by muse, varscan2
- IVD | c.879dup p.P294Afs*38 (on ENST00000651168; = p.P291Afs*38 on NM_002225.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 39/197 reads (20%) | catalogued as rs759159766; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MMACHC | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs556977618, CS109261, CS137052; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 28/168 reads (17%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 22/143 reads (15%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC52A3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs778479139; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM43 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs63750743, CM081452, COSV53206958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UROC1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852795, CM093242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1775del p.G592Afs*17 | Frame Shift Del (DEL) | VAF 46/266 reads (17%) | catalogued as rs766144819; called by mutect2, pindel, varscan2
- ABCA2 | c.6583C>T p.R2195W (on ENST00000614293; = p.R2165W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs745775868; called by muse, mutect2, varscan2
- ABCA2 | c.6202C>T p.R2068W (on ENST00000614293; = p.R2038W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775791084, COSV55808029; called by muse, varscan2
- ABCA2 | c.5264G>A p.R1755H (on ENST00000614293; = p.R1725H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs547824151; called by muse, mutect2, varscan2
- ABCC9 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs374849789; called by muse, mutect2, varscan2
- AC006059.2 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV59606417; called by muse, mutect2, varscan2
- AC008397.2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326213719, COSV53210247; called by muse, mutect2, varscan2
- AC068580.4 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.835); catalogued as rs1565022412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC069544.2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs768124188; called by muse, mutect2, varscan2
- ACAN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs376202313; called by muse, mutect2, varscan2
- ACTR8 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs111613351; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs369868105; called by muse, mutect2, varscan2
- ADAM33 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1339103730; called by muse, mutect2, varscan2
- ADAMTS14 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs376783762; called by muse, mutect2, varscan2
- ADAMTS17 | c.1721del p.P575Lfs*13 | Frame Shift Del (DEL) | VAF 28/185 reads (15%) | catalogued as rs779966272; called by mutect2, pindel, varscan2
- ADAMTS2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752401488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS7 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs143462516, COSV101183007; called by muse, mutect2, varscan2
- ADAT3 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs764986612, COSV60191966; called by muse, mutect2, varscan2
- ADCY1 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562735052, COSV52036386; called by muse, mutect2
- ADGRG6 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1246600532, COSV99747177; called by muse, mutect2, varscan2
- ADGRG7 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs150136013; called by muse, varscan2
- AFAP1L2 | c.2206A>C p.S736R | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1233051769; called by muse, mutect2, varscan2
- AFDN | c.4808C>T p.A1603V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as rs759940319, COSV60047991; called by muse, mutect2, varscan2
- AFF3 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1304982504, COSV57862515; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as COSV58317085; called by mutect2, pindel, varscan2
- AGFG2 | c.239del p.P80Lfs*9 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs1395902870; called by mutect2, pindel
- AGTRAP | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142151801; called by muse, mutect2, varscan2
- ALDH6A1 | c.598A>G p.M200V | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs376584594; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs1341338515; called by mutect2, varscan2
- ALYREF | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs1280360311, COSV100485905; called by muse, mutect2, varscan2
- AMFR | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs1253081413, COSV51919894; called by muse, mutect2, varscan2
- ANKRD11 | c.5777del p.P1926Rfs*37 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | catalogued as COSV99970806; called by mutect2, pindel, varscan2
- ANKRD34B | c.1247del p.P416Qfs*4 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs779065930, COSV100103683; called by mutect2, pindel, varscan2
- ANKRD6 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1301881122; called by muse, varscan2
- ANO2 | c.2266G>A p.V756M (on ENST00000356134 / NM_001278597.3; = p.V760M on NM_001278596.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199625786, COSV59036482; called by muse, mutect2, varscan2
- ANXA5 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187499448; called by muse, mutect2, varscan2
- ANXA7 | c.239del p.G80Efs*92 (on ENST00000372919 / NM_001320880.2; = p.G80Efs*70 on NM_001156.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | catalogued as COSV65822973; called by mutect2, pindel, varscan2
- APBA3 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs759204503, COSV53661039; called by mutect2, varscan2
- APBB1 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.878); catalogued as rs1446244825; called by muse, mutect2, varscan2
- APLP2 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141028580; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 38/252 reads (15%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs566681425, COSV100305649; called by muse, mutect2, varscan2
- ARHGAP22 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1159667835; called by muse, mutect2, varscan2
- ARHGAP27 | c.2338G>A p.E780K (on ENST00000428638 / NM_001282290.1; = p.E439K on NM_199282.3) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1356084965, COSV65357900; called by muse, mutect2, varscan2
- ARHGAP28 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1384102204; called by muse, mutect2, varscan2
- ARHGDIA | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1163390986; called by muse, mutect2
- ARHGEF17 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); catalogued as COSV55231091; called by muse, mutect2, varscan2
- ARHGEF25 | c.516_517del p.K173Nfs*30 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs765026555; called by pindel, varscan2
- ARMCX2 | c.469A>C p.M157L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100168242; called by muse, mutect2, varscan2
- ARSH | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1481449790; called by muse, mutect2, varscan2
- ASB13 | c.361del p.L121Cfs*6 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as COSV63090510; called by mutect2, pindel, varscan2
- ASCL1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57152740; called by muse, mutect2, varscan2
- ASH1L | c.4247_4249del p.S1416del | In Frame Del (DEL) | VAF 26/146 reads (18%) | catalogued as rs772496079; called by pindel, varscan2
- ASL | c.720C>T p.A240= | Splice Region (SNP) | VAF 68/313 reads (22%) | catalogued as rs764072757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPDH | c.694C>T p.P232S (on ENST00000389208 / NM_001114598.2; = p.P127S on NM_001024656.3) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs753754071; called by muse, mutect2, varscan2
- ASTN2 | c.1590C>T p.T530= (on ENST00000313400 / NM_001365069.1; = p.T479= on NM_014010.5) | Splice Region (SNP) | VAF 17/88 reads (19%) | catalogued as rs761405388, COSV57769233, COSV57772604; called by muse, mutect2, varscan2
- ATG2A | c.3883C>T p.R1295W | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs370525808; called by muse, mutect2, varscan2
- ATG9A | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764945140, COSV60134495; called by muse, mutect2, varscan2
- ATP13A4 | c.2581G>A p.V861M | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs143538005; called by muse, mutect2, varscan2
- ATP1A3 | c.257C>T p.P86L (on ENST00000545399 / NM_001256214.2; = p.P73L on NM_152296.5) | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1161880070, COSV57485078; called by muse, mutect2, varscan2
- ATP5PD | c.217_219del p.K73del | In Frame Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs746722852; called by pindel, varscan2
- ATP6V1B1 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 86/405 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99314273; called by muse, mutect2, varscan2
- ATRNL1 | c.2432T>A p.V811E | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV58111128; called by muse, mutect2, varscan2
- ATXN2L | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs774580137; called by mutect2, varscan2
- B4GALNT1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.153); catalogued as rs761637341; called by muse, mutect2, varscan2
- BARX1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.114); catalogued as COSV54159386; called by muse, mutect2, varscan2
- BCORL1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.573); catalogued as rs143414966, COSV54399360; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 26/89 reads (29%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BICC1 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs772959946, COSV54066846, COSV99570549; called by muse, mutect2, varscan2
- BLK | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142772999; called by muse, mutect2, varscan2
- BMP3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 66/351 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs138962672; called by muse, mutect2, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- BMPR2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as rs570953336, COSV65809762; called by muse, mutect2, varscan2
- BOC | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs764872369; called by muse, mutect2, varscan2
- BRAF | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs397507472, COSV56068050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD16 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs193253606, COSV99584696; called by muse, mutect2, varscan2
- BTBD8 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774884224, COSV64883698; called by muse, mutect2, varscan2
- C12orf4 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs765666105; called by muse, mutect2, varscan2
- C12orf66 | c.146dup p.S50Qfs*50 | Frame Shift Ins (INS) | VAF 36/192 reads (19%) | catalogued as rs771314426; called by mutect2, pindel, varscan2
- C1QTNF9 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs957406279; called by muse, mutect2, varscan2
- C1orf159 | c.180+1G>A p.X60_splice | Splice Site (SNP) | VAF 31/185 reads (17%) | catalogued as rs759922561, COSV53879495; called by muse, mutect2, varscan2
- C2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs771081314, COSV54961484; called by muse, mutect2, varscan2
- C5orf47 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV60864716; called by muse, mutect2, varscan2
- CACNA1D | c.2222A>C p.Y741S (on ENST00000350061 / NM_001128840.3; = p.Y761S on NM_000720.4) | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55468476; called by muse, mutect2, varscan2
- CACNA1F | c.2396A>G p.E799G | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs782376724; called by muse, mutect2, varscan2
- CACNA1I | c.5306C>T p.P1769L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs751904410; called by muse, mutect2
- CASR | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs755997016, COSV56139386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC130 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368944714; called by muse, mutect2, varscan2
- CCDC144A | c.3787A>G p.T1263A | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV60701351; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC73 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754011770; called by muse, mutect2
- CCNJL | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766921931, COSV57447012; called by muse, mutect2, varscan2
- CD86 | c.742T>C p.W248R (on ENST00000330540 / NM_175862.5; = p.W242R on NM_006889.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52610290; called by muse, mutect2, varscan2
- CD8B | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs768017195; called by muse, mutect2, varscan2
- CDC42BPB | c.4708C>T p.R1570* | Nonsense Mutation (SNP) | VAF 27/168 reads (16%) | catalogued as rs1416279074, COSV63474703; called by muse, mutect2, varscan2
- CDH11 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as rs750090961, COSV51775518; called by muse, mutect2, varscan2
- CDH15 | c.1537del p.H513Tfs*9 | Frame Shift Del (DEL) | VAF 61/330 reads (18%) | catalogued as rs763850576, COSV57025343; called by mutect2, pindel, varscan2
- CDH23 | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs372636295; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- CELSR2 | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs746280059, COSV54772694; called by muse, varscan2
- CELSR3 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.174); catalogued as COSV51185204; called by muse, mutect2, varscan2
- CEP112 | c.2766A>C p.E922D (on ENST00000392769 / NM_001353127.1; = p.E178D on NM_001037325.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100438976; called by muse, mutect2, varscan2
- CEP72 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs199729073; called by muse, varscan2
- CES5A | c.1422C>T p.F474= | Splice Region (SNP) | VAF 12/63 reads (19%) | catalogued as rs369099039; called by muse, mutect2, varscan2
- CFHR3 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100807666; called by muse, mutect2, varscan2
- CH25H | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs757604765; called by muse, mutect2, varscan2
- CHD4 | c.4547_4549del p.K1516del (on ENST00000357008 / NM_001363606.2; = p.K1529del on NM_001273.5) | In Frame Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs745414096; called by pindel, varscan2
- CHD6 | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV58556065; called by muse, mutect2, varscan2
- CHD8 | c.4316A>G p.H1439R (on ENST00000646647 / NM_001170629.2; = p.H1160R on NM_020920.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs968246339; called by mutect2, varscan2
- CHDH | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.182); catalogued as rs763294547, COSV59459766; called by muse, mutect2, varscan2
- CHPF2 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs776052782, COSV50393588; called by muse, mutect2, varscan2
- CHRD | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99200470; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 153/822 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs139552324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB4 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs746284415, COSV55715540; called by muse, mutect2, varscan2
- CHSY3 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59271231; called by muse, mutect2, varscan2
- CLDN18 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV59302390; called by muse, mutect2, varscan2
- CLIP1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1044706251; called by muse, mutect2, varscan2
- CLN6 | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 81/429 reads (19%) | catalogued as CX031926; called by muse, mutect2, varscan2
- CNKSR2 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54267418; called by muse, mutect2
- CNTNAP2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as rs756180841, COSV100662536, COSV62150589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL18A1 | c.3409G>A p.V1137I (on ENST00000359759 / NM_130444.3; = p.V902I on NM_030582.4) | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs750722061, COSV60589170; called by muse, mutect2, varscan2
- COL7A1 | c.7438C>T p.R2480W | Missense Mutation (SNP) | VAF 99/501 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs113508522, COSV100095107; called by muse, mutect2, varscan2
- COPS5 | c.921-5del | Splice Region (DEL) | VAF 16/70 reads (23%) | catalogued as rs200155628; called by mutect2, varscan2
- CPAMD8 | c.3896C>T p.A1299V (on ENST00000651564; = p.A1252V on NM_015692.5) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV101488600; called by muse, mutect2, varscan2
- CPSF1 | c.4094C>T p.A1365V | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs781861337; called by muse, mutect2, varscan2
- CPSF1 | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782779067; called by muse, mutect2, varscan2
- CREBZF | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99476105; called by muse, mutect2, varscan2
- CRHBP | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1378682406; called by muse, mutect2, varscan2
- CRHR2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as rs367951133; called by muse, mutect2, varscan2
- CRIM1 | c.2056T>A p.Y686N | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99752726; called by muse, mutect2, varscan2
- CRLF2 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs757079410, COSV101053734; called by muse, mutect2, varscan2
- CROCC2 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs952188462, COSV101376342; called by muse, mutect2, varscan2
- CSMD1 | c.4370C>T p.T1457M (on ENST00000520002; = p.T1456M on NM_033225.6) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758585923, COSV59377060; called by muse, mutect2, varscan2
- CTAGE9 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1448871181, COSV100020357; called by muse, mutect2, varscan2
- CTU1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1477885551; called by muse, mutect2, varscan2
- CYP4A11 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1241859582, COSV60226029; called by muse, mutect2, varscan2
- CYP4F11 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs750569824; called by muse, mutect2, varscan2
- DCAF13 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1431199702, COSV52570582; called by mutect2, varscan2
- DCLRE1C | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.143); catalogued as rs757865212, COSV63184400; called by muse, mutect2, varscan2
- DCST1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs372006655; called by muse, mutect2, varscan2
- DCST2 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV55050150; called by muse, mutect2, varscan2
- DCSTAMP | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs200594066; called by muse, mutect2, varscan2
- DDX27 | c.2072A>G p.K691R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs1490408347, COSV65593776, COSV65602451; called by muse, mutect2, varscan2
- DECR1 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs770345828, COSV55170110; called by muse, mutect2, varscan2
- DENND4B | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774045288; called by muse, mutect2, varscan2
- DGKQ | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs1335544382; called by muse, mutect2, varscan2
- DGKQ | c.384del p.L129Sfs*172 | Frame Shift Del (DEL) | VAF 24/155 reads (15%) | catalogued as rs1421409974; called by mutect2, pindel, varscan2
- DISC1 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV100790273; called by muse, mutect2, varscan2
- DNAH1 | c.5849C>T p.P1950L | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745715244; called by muse, mutect2, varscan2
- DNAH10 | c.3470G>A p.R1157K (on ENST00000409039; = p.R1096K on NM_207437.3) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1306065777, COSV101292149; called by muse, mutect2, varscan2
- DNAH10 | c.8837C>T p.A2946V (on ENST00000409039; = p.A2885V on NM_207437.3) | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs201720388, COSV68994148; called by muse, mutect2, varscan2
- DNAJB2 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs750175376, COSV60676590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNHD1 | c.6665G>A p.R2222H | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs187136087, COSV54437210; called by muse, mutect2, varscan2
- DNHD1 | c.12281C>T p.P4094L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs539569885; called by muse, mutect2, varscan2
- DOCK10 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.937); catalogued as rs778295369; called by muse, mutect2, varscan2
- DOCK6 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs764914767, COSV99625869; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 29/182 reads (16%) | catalogued as rs748134881; called by mutect2, varscan2
- DOK3 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 82/430 reads (19%) | catalogued as rs1216609044; called by muse, mutect2, varscan2
- DPH2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as rs775750438, COSV52544450; called by mutect2, varscan2
- DRD5 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs756703093, COSV58577931; called by muse, mutect2, varscan2
- DSC3 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as rs569043747; called by muse, mutect2, varscan2
- DUSP18 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs772310401; called by muse, mutect2, varscan2
- DXO | c.1128A>G p.I376M | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100514690; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs772082432; called by mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EFCC1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs554907927; called by muse, mutect2, varscan2
- ELL3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs751833360, COSV55855456; called by mutect2, varscan2
- ELMO1 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209023342, COSV60300078, COSV60300321; called by muse, mutect2, varscan2
- ELOVL1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs769555812; called by muse, mutect2, varscan2
- ELSPBP1 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs145971035; called by muse, mutect2, varscan2
- EML6 | c.4018C>T p.R1340* | Nonsense Mutation (SNP) | VAF 32/147 reads (22%) | catalogued as COSV62869783; called by muse, mutect2, varscan2
- EML6 | c.5662G>A p.A1888T | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284489828, COSV58265992; called by muse, mutect2, varscan2
- EPHX2 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs542880196, COSV66846330; called by muse, mutect2, varscan2
- ETV5 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60501650; called by muse, mutect2, varscan2
- EXOC2 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755697381, COSV100034341, COSV57864357; called by mutect2, varscan2
- EXOC3L1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385078509; called by muse, mutect2, varscan2
- FAM160A2 | c.1679G>A p.R560H (on ENST00000449352 / NM_001098794.2; = p.R574H on NM_032127.4) | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs1198127019; called by muse, mutect2, varscan2
- FAM234A | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536516737, COSV51451765; called by muse, mutect2, varscan2
- FAM43B | c.819C>G p.D273E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs772887704, COSV60579946; called by muse, mutect2, varscan2
- FAM71A | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1221070222, COSV54235569; called by muse, mutect2, varscan2
- FANCD2 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767659342; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs746983128; called by mutect2, varscan2
- FASN | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 139/713 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753970857, COSV100148109; called by muse, mutect2, varscan2
- FAT3 | c.2777del p.L926* | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | catalogued as COSV53090267; called by mutect2, pindel, varscan2
- FBN3 | c.3557C>T p.S1186L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs748408888; called by muse, mutect2, varscan2
- FBRSL1 | c.2497A>G p.K833E | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as rs891035241; called by muse, mutect2, varscan2
- FBXL7 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239863082, COSV61640555; called by muse, mutect2, varscan2
- FBXW7 | c.1877C>A p.A626D (on ENST00000281708 / NM_001349798.2; = p.A546D on NM_018315.5) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55906078, COSV55908924; called by muse, mutect2, varscan2
- FES | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1034352374; called by muse, mutect2, varscan2
- FMNL2 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as rs1367663865; called by muse, mutect2, varscan2
- FN3KRP | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745901308, COSV53928854; called by muse, mutect2, varscan2
- FNBP4 | c.1483dup p.I495Nfs*3 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs761053163; called by mutect2, pindel, varscan2
- FNDC1 | c.3814G>A p.V1272I | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs61738486; called by muse, mutect2
- FOXB1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101249926; called by muse, varscan2
- FOXD4L1 | c.1152A>T p.Q384H | Missense Mutation (SNP) | VAF 156/327 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV52075072; called by muse, mutect2, varscan2
- FOXD4L4 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 47/472 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1464947573; called by muse, mutect2, varscan2
- FOXE1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867894807; called by muse, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs760347049; called by mutect2, pindel
- FOXN4 | c.1328T>C p.F443S | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54493443; called by muse, mutect2, varscan2
- FSHR | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468699600; called by muse, mutect2, varscan2
- FUCA1 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs149277420; called by muse, mutect2, varscan2
- FUT1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1445377166; called by muse, mutect2
- FUT7 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs769102782; called by muse, mutect2, varscan2
- FYB2 | c.1153del p.M385* | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | catalogued as rs762431846; called by mutect2, pindel, varscan2
- FZD7 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53808039; called by muse, mutect2, varscan2
- FZD7 | c.1456C>A p.L486M | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs759120037; called by muse, mutect2
- GALNT10 | c.747del p.L250Cfs*16 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs540440277; called by mutect2, pindel
- GALR3 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV50763884; called by muse, mutect2, varscan2
- GATB | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs770684034; called by muse, mutect2, varscan2
- GC | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 48/367 reads (13%) | catalogued as rs774755036, COSV56740398; called by muse, mutect2, varscan2
- GCNT7 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs1044585477; called by muse, mutect2, varscan2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs761897305; called by mutect2, varscan2
- GDPD2 | c.47A>G p.H16R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs781088307; called by muse, varscan2
- GIT1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs1335529772; called by muse, mutect2, varscan2
- GJC2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.08); catalogued as rs1457307938; called by muse, varscan2
- GNB1L | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs765685532, COSV61547693; called by muse, mutect2, varscan2
- GOLGA3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs201001117; called by muse, mutect2, varscan2
- GPR26 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1405244525, COSV52936549; called by muse, mutect2, varscan2
- GRID2IP | c.3122C>T p.T1041M | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969577691; called by muse, mutect2, varscan2
- GRIN1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs754711981; called by muse, mutect2, varscan2
- GRM6 | c.1155C>T p.G385= | Splice Region (SNP) | VAF 33/242 reads (14%) | catalogued as rs746668802, COSV51445910; called by muse, mutect2, varscan2
- GSTT2B | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 47/226 reads (21%) | catalogued as rs1332115451; called by muse, mutect2, varscan2
- GTF2IRD2B | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs782552756; called by muse, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- GUCY2D | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs147586061; called by muse, mutect2, varscan2
- H2BC14 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs761877155, COSV60798692; called by mutect2, varscan2
- HEATR5B | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1348780312, COSV51848963; called by muse, mutect2, varscan2
- HECW2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as rs138277290; called by muse, mutect2, varscan2
- HERC1 | c.12607G>A p.A4203T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1258480212; called by muse, mutect2, varscan2
- HERC6 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs755742691; called by muse, mutect2, varscan2
- HIC1 | c.452G>A p.R151H (on ENST00000322941 / NM_001098202.1; = p.R132H on NM_006497.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1485518057; called by muse, varscan2
- HIVEP1 | c.4382C>T p.A1461V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV65104566; called by muse, mutect2, varscan2
- HIVEP1 | c.6838C>T p.R2280C | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as rs868438390; called by muse, mutect2, varscan2
- HJV | c.662C>T p.T221I (on ENST00000336751 / NM_213653.4; = p.T108I on NM_145277.5) | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100382161; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | catalogued as rs199474609; called by mutect2, varscan2
- HLA-DOA | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs565438950, COSV57714546; called by muse, mutect2, varscan2
- HOXA3 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs775867530; called by muse, mutect2, varscan2
- HPD | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368438884; called by muse, mutect2, varscan2
- HSF4 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 62/358 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99263640; called by muse, mutect2, varscan2
- HTR1A | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 107/582 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746421729, COSV60503493; called by muse, mutect2, varscan2
- HTT | c.9070C>T p.H3024Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.597); catalogued as COSV100751474; called by muse, mutect2, varscan2
- ICAM2 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.21); catalogued as rs751902761; called by muse, mutect2, varscan2
- IFIT2 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV99260158; called by muse, mutect2, varscan2
- IGFLR1 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 55/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766455368, COSV53074438; called by muse, mutect2, varscan2
- IGLV3-21 | c.128dup p.N44Kfs*6 | Frame Shift Ins (INS) | VAF 25/219 reads (11%) | catalogued as rs756723195; called by mutect2, pindel, varscan2
- IGSF8 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs150306822; called by muse, mutect2, varscan2
- INO80D | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373225135; called by mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCB1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs773338261; called by muse, mutect2, varscan2
- IQSEC3 | c.1331C>T p.A444V (on ENST00000538872 / NM_001170738.2; = p.A141V on NM_015232.1) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs571548221, COSV100407911; called by muse, mutect2, varscan2
- ITIH2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs376208756; called by mutect2, varscan2
- ITPR3 | c.3550G>A p.G1184R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.548); catalogued as rs755754723; called by muse, mutect2, varscan2
- ITPRID1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99064531; called by muse, varscan2
- JAK1 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781744573; called by muse, mutect2, varscan2
- JMJD1C | c.4262C>T p.S1421L | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.49); catalogued as COSV100550033; called by muse, mutect2, varscan2
- KASH5 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs754302808, COSV71357950; called by muse, mutect2, varscan2
- KAT8 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99571316; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNC2 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867162755; called by muse, mutect2, varscan2
- KCNJ14 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1238345127; called by muse, mutect2, varscan2
- KCNN1 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.277); catalogued as rs751351847; called by muse, mutect2, varscan2
- KCNN3 | c.1988G>A p.R663Q (on ENST00000618040 / NM_001204087.1; = p.R648Q on NM_002249.6) | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1423319449; called by muse, varscan2
- KDM2B | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs575953168, COSV65644189; called by muse, mutect2, varscan2
- KDM5B | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs988280642; called by muse, mutect2, varscan2
- KHDC4 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs542119476, COSV64164650; called by muse, mutect2, varscan2
- KIAA0895 | c.584G>A p.G195D (on ENST00000297063 / NM_001100425.2; = p.G144D on NM_015314.3) | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); catalogued as COSV99766730; called by muse, mutect2, varscan2
- KIAA1549L | c.3430G>A p.A1144T (on ENST00000321505; = p.A1441T on NM_012194.3) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as rs373127794; called by muse, mutect2, varscan2
- KIDINS220 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs761044466, COSV56751745; called by muse, mutect2, varscan2
- KIF12 | c.875A>G p.N292S (on ENST00000640217; = p.N154S on NM_138424.1) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315948870; called by muse, mutect2, varscan2
- KIF26B | c.3166G>A p.V1056M | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs377378352; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs754171400, COSV63285253; called by mutect2, varscan2
- KPNB1 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV51596458; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT15 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs768028727, COSV54180255; called by muse, mutect2, varscan2
- KRT20 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1192320676, COSV51424303; called by muse, mutect2, varscan2
- L3MBTL2 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as rs151099443; called by muse, mutect2, varscan2
- LAD1 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199664903, COSV100943845; called by muse, mutect2, varscan2
- LAMC3 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs193039706, COSV63091299; called by muse, mutect2, varscan2
- LARP6 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.626); catalogued as rs1246203639; called by muse, mutect2, varscan2
- LHX5 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs779419542; called by muse, mutect2, varscan2
- LHX6 | c.1020del p.V341Sfs*164 (on ENST00000373755 / NM_001242334.2; = p.V370Sfs*164 on NM_014368.5) | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as COSV100493338; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNX2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs146404836; called by muse, mutect2, varscan2
- LRFN1 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.02); catalogued as COSV99952638; called by muse, mutect2, varscan2
- LRFN3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.34); catalogued as rs1007228504; called by muse, mutect2, varscan2
- LRRC4B | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV65349201; called by muse, mutect2, varscan2
- LRRC71 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs896166838; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- LRRTM1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs368510654, COSV54445714; called by muse, mutect2
- LUC7L | c.704del p.K235Sfs*10 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | catalogued as COSV99551483; called by mutect2, pindel, varscan2
- LY75 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758257235; called by mutect2, varscan2
- MAK16 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201215286; called by muse, mutect2, varscan2
- MAMDC4 | c.3538_3540del p.K1180del (on ENST00000445819; = p.K1101del on NM_206920.3) | In Frame Del (DEL) | VAF 30/176 reads (17%) | catalogued as rs769057784; called by pindel, varscan2
- MAN2A1 | c.1404del p.F468Lfs*22 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs766462976; called by mutect2, pindel, varscan2
- MAN2A2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 102/575 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs765974628, COSV64639767; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP3K7 | c.1696C>T p.R566C (on ENST00000369329 / NM_145331.3; = p.R539C on NM_003188.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100997438; called by muse, mutect2, varscan2
- MARF1 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751579883; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MCF2L | c.991G>A p.E331K (on ENST00000375608; = p.E299K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs561285154, COSV65048087; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs746910913; called by mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED12L | c.1011del p.G338Afs*4 | Frame Shift Del (DEL) | VAF 23/136 reads (17%) | catalogued as COSV56379857; called by mutect2, varscan2
- MED15 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1473952069; called by muse, mutect2, varscan2
- MEGF8 | c.2455G>A p.E819K (on ENST00000251268 / NM_001271938.2; = p.E752K on NM_001410.3) | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs1424452415; called by muse, mutect2, varscan2
- METTL21A | c.22_24del p.E8del | In Frame Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs764328321; called by pindel, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 24/163 reads (15%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs762448666; called by mutect2, varscan2
- MINAR1 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs772906295; called by muse, mutect2, varscan2
- MKI67 | c.8381C>T p.A2794V | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs770048676; called by muse, mutect2, varscan2
- MKRN3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1355723562, COSV58812455; called by muse, mutect2, varscan2
- MLXIP | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780988464; called by muse, mutect2, varscan2
- MLYCD | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773101554; called by mutect2, varscan2
- MOBP | c.452G>A p.R151H (on ENST00000420739; = p.R175H on NM_001278322.2) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | PolyPhen possibly damaging (0.49); catalogued as rs1461276367; called by muse, mutect2, varscan2
- MPEG1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs377026755; called by muse, mutect2, varscan2
- MROH2B | c.7_10del p.L3Vfs*6 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | catalogued as rs1561312261; called by mutect2, pindel, varscan2
- MRPL11 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.142); catalogued as rs1412375465; called by muse, mutect2, varscan2
- MSL3 | c.1319del p.P440Qfs*22 (on ENST00000312196 / NM_078629.4; = p.P274Qfs*22 on NM_006800.4) | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | catalogued as rs768515139; called by pindel, varscan2
- MTBP | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs548643877, COSV59966733; called by muse, mutect2
- MTMR3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1256689376; called by muse, mutect2, varscan2
- MTNR1B | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs763233986; called by muse, varscan2
- MTUS2 | c.4022C>T p.P1341L (on ENST00000612955 / NM_001366650.1; = p.P320L on NM_015233.6) | Missense Mutation (SNP) | VAF 61/325 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66421387; called by muse, mutect2, varscan2
- MUC4 | c.14228G>A p.R4743H (on ENST00000463781 / NM_018406.7; = p.R507H on NM_004532.6) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs921640013; called by muse, mutect2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPC2 | c.1925del p.P642Rfs*34 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as rs752111099; called by mutect2, pindel, varscan2
- MYG1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs11552382, COSV52932238; called by mutect2, varscan2
- MYH10 | c.775del p.A259Pfs*37 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as COSV52608910; called by mutect2, pindel, varscan2
- MYH14 | c.5179C>T p.R1727W | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766866459; called by muse, mutect2, varscan2
- MYO18A | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.971); catalogued as rs746761580; called by muse, mutect2, varscan2
- MYO1G | c.2011G>A p.V671M | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759400828, COSV51854774; called by muse, mutect2, varscan2
- MYO7B | c.4009G>A p.V1337M | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs760860620; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- MYRIP | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759560655, COSV56873983; called by muse, mutect2, varscan2
- MZF1 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.679); catalogued as COSV53040868; called by muse, mutect2, varscan2
- NAGPA | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | PolyPhen benign (0.003); catalogued as rs781569034; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NBAS | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV55733851; called by muse, mutect2, varscan2
- NBEA | c.6227G>A p.R2076H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172372804, COSV100077859; called by muse, mutect2, varscan2
- NBPF12 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1194973724; called by muse, mutect2, varscan2
- NCKAP1L | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1265995510, COSV53211580; called by muse, mutect2, varscan2
- NCKIPSD | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 78/464 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1018892440, COSV53660677; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 45/278 reads (16%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NDUFA10 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs750076568, COSV53154873; called by muse, mutect2, varscan2
- NETO2 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs772817589, COSV57452814; called by muse, mutect2, varscan2
- NEURL1B | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs530003530; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NKX2-2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV65820230; called by muse, mutect2, varscan2
- NLN | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as rs777445940; called by muse, varscan2
- NLRP14 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 94/510 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs139691301, COSV55064710; called by muse, mutect2, varscan2
- NLRP8 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267855509; called by muse, mutect2, varscan2
- NOA1 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs752978677; called by muse, mutect2, varscan2
- NOMO1 | c.3661C>T p.R1221W | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs747726997; called by muse, mutect2
- NPC1 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777156729, COSV52576826; ClinVar: uncertain significance; called by muse, varscan2
- NUP188 | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs200670335; called by muse, mutect2, varscan2
- NUP62 | c.254del p.G85Efs*15 | Frame Shift Del (DEL) | VAF 63/308 reads (20%) | catalogued as rs1568701637; called by mutect2, pindel, varscan2
- OBSCN | c.16505C>T p.A5502V | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs748915504; called by muse, mutect2, varscan2
- OGDHL | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759416739; called by muse, mutect2, varscan2
- OR6C1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs757334431, COSV65573206; called by muse, mutect2
- OR8H3 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs751685926, COSV57909832, COSV57912321; called by muse, mutect2, varscan2
- OSBPL3 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746730200, COSV57662549; called by muse, mutect2
- OSM | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as rs200095730; called by muse, mutect2, varscan2
- OTOGL | c.2641C>A p.P881T (on ENST00000547103; = p.P872T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs1263813257; called by muse, mutect2, varscan2
- P2RY13 | c.702del p.V235Yfs*81 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs771457469; called by mutect2, pindel, varscan2
- P2RY2 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.194); catalogued as rs549007337; called by muse, mutect2, varscan2
- PALM | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as rs944193184; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 60/283 reads (21%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDH11X | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs750630182, COSV53438545, COSV53474797; called by muse, mutect2, varscan2
- PCDH8 | c.2740G>A p.G914S | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.883); catalogued as COSV58812907; called by muse, mutect2, varscan2
- PCDH9 | c.3140C>T p.S1047L (on ENST00000377865 / NM_203487.3; = p.S1013L on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs763000199, COSV60541113; called by muse, mutect2, varscan2
- PCDHA10 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 155/798 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as rs375062704, COSV56527999; called by muse, mutect2, varscan2
- PCDHA2 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 97/485 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65365768; called by muse, mutect2, varscan2
- PCDHB1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs900032895; called by muse, mutect2, varscan2
- PCDHGA1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 21/525 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV65296950; called by muse, mutect2
- PCDHGA2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as rs868424998; called by muse, mutect2, varscan2
- PCOLCE | c.483dup p.R162Afs*45 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | catalogued as rs761254301; called by mutect2, pindel, varscan2
- PDE4A | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.067); catalogued as COSV61796410; called by mutect2, varscan2
- PDE8B | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769265994; called by muse, mutect2, varscan2
- PFKP | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424918673, COSV101126689; called by muse, mutect2, varscan2
- PHKG1 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51918160; called by muse, mutect2
- PHLDB1 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61876830; called by muse, mutect2, varscan2
- PHOX2A | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53355042, COSV53356398; called by muse, mutect2, varscan2
- PI4K2A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773047134, COSV65701109; called by muse, mutect2, varscan2
- PI4KA | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs141064047; called by muse, mutect2, varscan2
- PKD2L1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.111); catalogued as rs145997401, COSV58394861; called by muse, mutect2, varscan2
- PLA2G1B | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV100387515; called by muse, mutect2, varscan2
- PLCXD3 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); catalogued as rs1042533453, COSV100125376; called by muse, mutect2, varscan2
- PLPP3 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs753280597, COSV64840469; called by muse, mutect2, varscan2
- PLPPR3 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs746621782, COSV62459000; called by mutect2, varscan2
- PLXNB2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1307927339, COSV63782920; called by muse, mutect2, varscan2
- PM20D1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs199717760, COSV65648532; called by muse, mutect2, varscan2
- PMFBP1 | c.1936C>T p.R646W (on ENST00000537465; = p.R641W on NM_031293.3) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1044938996, COSV52823820; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLR3K | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs745993040, COSV53452954; called by mutect2, varscan2
- POLRMT | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1216925925, COSV99241220; called by muse, mutect2, varscan2
- POMT2 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV55071374; called by muse, mutect2, varscan2
- POU4F3 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57942128; called by muse, mutect2, varscan2
- POU6F2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs768398366, COSV101302638; called by muse, mutect2, varscan2
- PPFIBP1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.886); catalogued as rs753478506; called by muse, mutect2, varscan2
- PPL | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs374905578; called by muse, mutect2, varscan2
- PPRC1 | c.4381C>A p.P1461T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs377047618, COSV99531607; called by muse, varscan2
- PRDM13 | c.185del p.G62Afs*7 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as COSV100980586, COSV65029971; called by mutect2, pindel, varscan2
- PREX1 | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs371681138; called by muse, mutect2, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs764069617; called by mutect2, varscan2
- PRKAR2B | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs76105568, COSV99708384; called by muse, mutect2, varscan2
- PROB1 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs776415258; called by muse, mutect2, varscan2
- PROX2 | c.1305+1A>G p.X435_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as rs767225030; called by mutect2, varscan2
- PRPF40A | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs781394480; called by mutect2, varscan2
- PRR33 | c.492del p.S165Vfs*106 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as rs746984967; called by mutect2, pindel, varscan2
- PRRG3 | c.494dup p.R166Qfs*14 | Frame Shift Ins (INS) | VAF 30/82 reads (37%) | catalogued as rs748526759; called by mutect2, varscan2
- PSG1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as rs534643202, COSV54948843; called by muse, mutect2, varscan2
- PSMB7 | c.455A>G p.H152R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99413182; called by muse, mutect2, varscan2
- PTCH1 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV59464131; called by muse, mutect2, varscan2
- PTCHD1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.459); catalogued as rs1569130423; called by muse, mutect2, varscan2
- PTDSS2 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1347348153; called by muse, mutect2, varscan2
- PTK2 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100569246; called by mutect2, varscan2
- PTK2B | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100593326; called by muse, mutect2, varscan2
- PTPN21 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60850228; called by muse, mutect2, varscan2
- PTPRT | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs750813623; called by muse, mutect2, varscan2
- PUM1 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1206383966, COSV57090690; called by muse, mutect2, varscan2
- PVRIG | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs763043735; called by muse, mutect2, varscan2
- PYGM | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs765962705, COSV51225838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QRICH1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771946633; called by mutect2, varscan2
- QRICH2 | c.4697A>G p.Y1566C | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757435127; called by mutect2, varscan2
- RAB11FIP2 | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs747204294, COSV62926248; called by muse, mutect2, varscan2
- RAB28 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1401637475, COSV56538158; called by muse, mutect2, varscan2
- RAB3D | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs540521854; called by muse, mutect2, varscan2
- RAB4B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs747053848, COSV63824679; called by muse, mutect2, varscan2
- RANBP3L | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs145127212; called by muse, mutect2, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBM5 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs758380885; called by muse, mutect2, varscan2
- RBP3 | c.3670G>A p.A1224T | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs546489667; called by muse, mutect2, varscan2
- REST | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1334359309, COSV58360344; called by mutect2, varscan2
- RGS3 | c.2744G>A p.R915H (on ENST00000350696 / NM_001282923.2; = p.R634H on NM_130795.4) | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776005314; called by muse, mutect2
- RHPN1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs761307864; called by muse, mutect2, varscan2
- RIF1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs776636521; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNH1 | c.273-1G>A p.X91_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as rs1353382892; called by muse, mutect2, varscan2
- ROBO3 | c.2342del p.G781Vfs*223 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | catalogued as rs751551948, COSV67303225; called by mutect2, pindel, varscan2
- ROR2 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774277014; called by muse, mutect2, varscan2
- RORB | c.118G>T p.G40C (on ENST00000396204 / NM_001365023.1; = p.G29C on NM_006914.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65333562; called by muse, mutect2, varscan2
- RPAP1 | c.3757G>A p.V1253M | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs143725774; called by muse, mutect2, varscan2
- RPGRIP1L | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.273); catalogued as rs1486460799; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTEL1 | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1406023071; called by muse, mutect2
- RUNX1T1 | c.1212del p.G405Vfs*22 (on ENST00000265814 / NM_001198628.1; = p.G378Vfs*22 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/156 reads (19%) | catalogued as rs1204452612, COSV56151707; called by mutect2, varscan2
- RXRA | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs771637845, COSV62684622; called by muse, mutect2, varscan2
- SCN1A | c.5510C>T p.P1837L (on ENST00000303395 / NM_001202435.3; = p.P1826L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs149225252, COSV57669951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs1215570894; called by muse, mutect2, varscan2
- SCN5A | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.532); catalogued as rs201641342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCPEP1 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774778044; called by mutect2, varscan2
- SDHC | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as rs148566767, COSV104418181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK2 | c.4888G>A p.V1630M | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs762632405; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SERPINB4 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs752728556; called by muse, mutect2, varscan2
- SFXN5 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs142620607; called by muse, mutect2, varscan2
- SGSM3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs138251871; called by muse, mutect2, varscan2
- SH3GL3 | c.795T>A p.S265R | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV61056034; called by muse, mutect2, varscan2
- SHANK3 | c.4370G>A p.R1457H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386255431; called by muse, mutect2, varscan2
- SHISA6 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100604193; called by muse, mutect2, varscan2
- SHOX | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs751747648, COSV61861657; called by muse, mutect2, varscan2
- SIGLEC9 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51584769; called by muse, mutect2, varscan2
- SIRPA | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100605159; called by muse, varscan2
- SLAIN1 | c.700+2T>C p.X234_splice (on ENST00000466548; = p.X92_splice on NM_001040153.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as rs769517212; called by muse, mutect2, varscan2
- SLAIN2 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1560467821, COSV51907346; called by muse, mutect2, varscan2
- SLC16A7 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs543596862, COSV53893187, COSV53900554; called by mutect2, varscan2
- SLC16A8 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1241550232; called by mutect2, varscan2
- SLC19A1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 47/271 reads (17%) | catalogued as rs1483220132; called by muse, mutect2, varscan2
- SLC25A23 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs199968517, COSV51200886; called by muse, mutect2, varscan2
- SLC35D3 | c.1065del p.A356Lfs*30 | Frame Shift Del (DEL) | VAF 41/221 reads (19%) | catalogued as COSV59378103, COSV59378110; called by mutect2, pindel, varscan2
- SLC35G3 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 98/529 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs143192040; called by muse, mutect2, varscan2
- SLC36A2 | c.440+1G>A p.X147_splice | Splice Site (SNP) | VAF 47/210 reads (22%) | catalogued as rs546263814; called by muse, mutect2, varscan2
- SLC38A4 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775214035, COSV99872864; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC6A18 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146563877; called by muse, mutect2, varscan2
- SLC8A2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1006556240, COSV99370358; called by muse, mutect2, varscan2
- SLX4 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200807331, COSV53562130; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 29/199 reads (15%) | catalogued as COSV50994213; called by muse, mutect2, varscan2
- SMARCC1 | c.1937C>T p.S646L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs767169855, COSV54381590; called by muse, mutect2, varscan2
- SMARCC2 | c.3583del p.L1195Cfs*88 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs1224281535; called by mutect2, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as rs758895137; called by mutect2, varscan2
- SOGA1 | c.4154C>T p.T1385M | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs376528729; called by muse, mutect2, varscan2
- SORCS1 | c.2572G>A p.V858I | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs201889963, COSV53879347; called by muse, mutect2, varscan2
- SPEG | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1311462718; called by muse, mutect2, varscan2
- SPEG | c.5695G>C p.A1899P | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs563985830, COSV100406053; called by muse, mutect2, varscan2
- SPTAN1 | c.2819G>A p.S940N | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs1395652109; called by muse, mutect2, varscan2
- SREBF2 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 53/235 reads (23%) | catalogued as rs1418941693, COSV63331298; called by muse, mutect2, varscan2
- SRGAP2 | c.2452A>C p.S818R (on ENST00000624873 / NM_001170637.4; = p.S819R on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1553377845; called by muse, mutect2, varscan2
- SRMS | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as rs373892181; called by mutect2, varscan2
- SSC5D | c.895+5G>A | Splice Region (SNP) | VAF 15/104 reads (14%) | catalogued as rs1199327063; called by muse, mutect2, varscan2
- SSTR1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 91/446 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57456221, COSV57457794; called by muse, mutect2, varscan2
- ST7 | c.1411C>T p.R471W (on ENST00000265437 / NM_021908.3; = p.R448W on NM_018412.4) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772278439, COSV55380371; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAM | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs370940096; called by muse, mutect2, varscan2
- STRN3 | c.1796del p.N599Ifs*42 (on ENST00000357479 / NM_001083893.2; = p.N515Ifs*42 on NM_014574.4) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as COSV62579233; called by mutect2, pindel, varscan2
- SULF2 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009178580, COSV100737126, COSV63418469; called by muse, mutect2, varscan2
- SUN1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775225289, COSV100568665, COSV61777720; called by muse, mutect2, varscan2
- SUN5 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs772515844, COSV62180114; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs753462162; called by mutect2, varscan2
- SYMPK | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs760395766; called by muse, mutect2, varscan2
- SYNE1 | c.22915G>A p.A7639T (on ENST00000367255 / NM_182961.4; = p.A7568T on NM_033071.3) | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as rs376169744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs377209812; called by muse, mutect2, varscan2
- SYNPO | c.1481del p.G494Afs*11 (on ENST00000394243 / NM_001166208.2; = p.G250Afs*11 on NM_007286.6) | Frame Shift Del (DEL) | VAF 43/201 reads (21%) | catalogued as COSV56939890; called by mutect2, pindel, varscan2
- SZT2 | c.9893G>A p.R3298H (on ENST00000634258 / NM_001365999.1; = p.R3241H on NM_015284.4) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1060499723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1C | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373837775; called by muse, mutect2, varscan2
- TANC1 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs960946605, COSV55087985; called by muse, mutect2, varscan2
- TAS2R14 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV101113743; called by mutect2, varscan2
- TBC1D31 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99782770; called by mutect2, varscan2
- TBCC | c.311del p.F104Sfs*2 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as rs773197480, COSV55130906; called by mutect2, pindel, varscan2
- TBX19 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs758895157, COSV63197601; called by muse, mutect2, varscan2
- TEC | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs1288931917; called by muse, varscan2
- TEX13A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100780581; called by muse, mutect2, varscan2
- TGFBR3 | c.328del p.L110Wfs*5 | Frame Shift Del (DEL) | VAF 26/232 reads (11%) | catalogued as COSV99283134; called by mutect2, pindel, varscan2
- THEMIS2 | c.1793_1795del p.I598del (on ENST00000373921 / NM_001286115.1; = p.H240del on NM_004848.3) | In Frame Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs780025757; called by pindel, varscan2
- THSD7A | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV70266287; called by muse, mutect2, varscan2
- THSD7B | c.3244C>T p.R1082C (on ENST00000272643; = p.R1080C on NM_001316349.2) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1431031275, COSV99757619; called by muse, mutect2, varscan2
- TIMM23 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1554915213; called by muse, mutect2, varscan2
- TINAGL1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as rs566858151, COSV54700029; called by muse, mutect2, varscan2
- TLL2 | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372644801; called by muse, mutect2, varscan2
- TLR5 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs746250566; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMEM132A | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771413372, COSV50002846; called by muse, mutect2, varscan2
- TMEM184C | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56855505; called by muse, varscan2
- TMEM59 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs776997328; called by muse, mutect2, varscan2
- TNFAIP1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 105/582 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782807411, COSV50229081; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2914G>A p.A972T | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs148640580; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TNS2 | c.1121G>A p.R374Q (on ENST00000314250 / NM_170754.4; = p.R384Q on NM_015319.2) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs188732040; called by muse, mutect2, varscan2
- TNS3 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1399893862, COSV60799911; called by muse, mutect2, varscan2
- TOP1 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs751834546, COSV63694126; called by muse, mutect2, varscan2
- TOPAZ1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV59074670; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs770561785; called by mutect2, varscan2
- TRDN | c.1050del p.E351Sfs*13 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs753514580; called by mutect2, varscan2
- TRIM10 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 44/234 reads (19%) | catalogued as rs576428211, COSV64998472; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as rs763121810; called by mutect2, varscan2
- TRIM68 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 54/451 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs199665620; called by muse, mutect2, varscan2
- TRMT6 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757764826; called by muse, mutect2, varscan2
- TRMT61A | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 67/430 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as rs762768998; called by muse, mutect2, varscan2
- TRMU | c.410_412del p.E137del | In Frame Del (DEL) | VAF 23/140 reads (16%) | catalogued as rs1191734880; called by pindel, varscan2
- TRPA1 | c.1274del p.G425Afs*5 | Frame Shift Del (DEL) | VAF 74/367 reads (20%) | catalogued as rs759260579; called by mutect2, varscan2
- TSTD2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1171603066; called by muse, mutect2, varscan2
- TTC14 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.219); catalogued as COSV56013912; called by muse, mutect2, varscan2
- TTF1 | c.668del p.K223Rfs*45 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | catalogued as rs765042099; called by mutect2, varscan2
- TTLL13P | c.838C>A p.H280N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.044); catalogued as COSV100296628; called by muse, mutect2, varscan2
- TTLL2 | c.1598G>A p.C533Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs953166663; called by muse, mutect2, varscan2
- TTN | c.46144G>A p.G15382R (on ENST00000591111; = p.G7958R on NM_003319.4) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | PolyPhen probably damaging (1); catalogued as rs745424139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA1C | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as rs370276397; called by muse, mutect2, varscan2
- TUBA8 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs758772460; called by muse, mutect2, varscan2
- TUBB4A | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 134/718 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.867); catalogued as rs941408562, COSV51153361; called by muse, mutect2, varscan2
- TULP4 | c.1207del p.R403Afs*24 | Frame Shift Del (DEL) | VAF 58/266 reads (22%) | catalogued as rs746002490; called by mutect2, pindel, varscan2
- TXLNG | c.1173del p.K391Nfs*7 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as COSV58112805; called by mutect2, pindel, varscan2
- UBAP2 | c.2248A>G p.S750G | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs749196714; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs763652408; called by mutect2, varscan2
- UHRF1BP1 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs1347709367; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3682G>A p.V1228M | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs755704730; called by muse, mutect2, varscan2
- ULK1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58854282; called by muse, mutect2, varscan2
- UNC5D | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs763472547, COSV54787957; called by muse, mutect2, varscan2
- UNC79 | c.7511C>T p.T2504M (on ENST00000393151 / NM_001346218.2; = p.T2327M on NM_020818.5) | Missense Mutation (SNP) | VAF 91/530 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as rs141618022; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs767420916; called by mutect2, varscan2
- USP31 | c.3539G>A p.R1180Q | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs775750903; called by muse, mutect2, varscan2
- USP42 | c.3707del p.K1236Rfs*92 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs759165525, COSV60363391; called by mutect2, varscan2
- USP54 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749203459, COSV60441812; called by muse, mutect2, varscan2
- VAV1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs775175030; called by muse, mutect2, varscan2
- VEZF1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as rs369149975; called by muse, mutect2, varscan2
- VGLL2 | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1419954813; called by muse, mutect2, varscan2
- VPS25 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs756981692; called by muse, mutect2, varscan2
- VPS53 | c.1675G>A p.A559T (on ENST00000571805 / NM_001366253.2; = p.A530T on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1009388889; called by muse, mutect2, varscan2
- VWA5B1 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1476778019, COSV99056004; called by muse, mutect2, varscan2
- VWA7 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1317969639, COSV63304507; called by muse, mutect2, varscan2
- WDR83 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54419486; called by muse, mutect2, varscan2
- WDR97 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 106/540 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1212195223; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIZ | c.5576G>A p.R1859Q (on ENST00000673675 / NM_001371589.1; = p.R764Q on NM_021241.3) | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.984); catalogued as rs766225979; called by mutect2, varscan2
- WNT7B | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs780469731; called by muse, mutect2, varscan2
- WRNIP1 | c.302A>G p.D101G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.892); catalogued as rs1194762411; called by muse, varscan2
- WSB1 | c.489_491del p.L164del | In Frame Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs1567688231; called by pindel, varscan2
- YBX1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs1463059319; called by muse, mutect2, varscan2
- YKT6 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs747509605; called by muse, mutect2, varscan2
- ZC3H12C | c.2552del p.P851Lfs*4 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | catalogued as COSV53710662; called by mutect2, pindel, varscan2
- ZC3H13 | c.4330G>A p.E1444K (on ENST00000242848 / NM_001330565.2; = p.E1445K on NM_015070.6) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as rs375805320; called by mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs372055076; called by muse, mutect2, varscan2
- ZDHHC19 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs770888668; called by mutect2, varscan2
- ZDHHC24 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs372147730; called by muse, mutect2, varscan2
- ZFP36L2 | c.683del p.G228Afs*233 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | catalogued as COSV99144234; called by mutect2, pindel, varscan2
- ZFP37 | c.498del p.K166Nfs*19 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as COSV100953148; called by mutect2, pindel, varscan2
- ZKSCAN1 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs532856250, COSV60873171; called by muse, mutect2, varscan2
- ZNF174 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.426); catalogued as rs1039890841; called by muse, mutect2, varscan2
- ZNF202 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60246738; called by muse, mutect2, varscan2
- ZNF208 | c.3215T>A p.L1072H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV68104579; called by mutect2, varscan2
- ZNF208 | c.2827A>T p.K943* | Nonsense Mutation (SNP) | VAF 26/176 reads (15%) | catalogued as COSV68109774; called by muse, mutect2, varscan2
- ZNF415 | c.697_698del p.V233Tfs*12 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | catalogued as rs750627295; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF575 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs373389943; called by muse, mutect2, varscan2
- ZNF648 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV100374352; called by muse, mutect2, varscan2
- ZNF649 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs762808376, COSV100031130; called by muse, mutect2, varscan2
- ZNF786 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1466860439; called by muse, mutect2, varscan2
- ZNF827 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771679311; called by muse, mutect2, varscan2
- ZNF831 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs576840472, COSV64038971; called by muse, mutect2, varscan2
- ZSCAN30 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759585403, COSV54349820; called by muse, mutect2, varscan2
- AADACL4 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AAR2 | c.629_630del p.E210Afs*14 | Frame Shift Del (DEL) | VAF 48/284 reads (17%) | called by pindel, varscan2
- ABCA4 | c.1943T>C p.M648T | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ABCA8 | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ABCF2 | c.1199del p.N400Mfs*2 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | called by mutect2, varscan2
- ABCG1 | c.1934del p.N645Mfs*108 | Frame Shift Del (DEL) | VAF 56/319 reads (18%) | called by mutect2, pindel, varscan2
- AC024940.1 | n.4204A>G | Splice Region (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
- ACE | c.2739+1G>T p.X913_splice | Splice Site (SNP) | VAF 60/365 reads (16%) | called by muse, mutect2, varscan2
- ACOT11 | c.1801T>C p.F601L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ACTA2 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 80/450 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADAMTS9 | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2171A>G p.Q724R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY8 | c.1387del p.D463Tfs*27 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- ADGB | c.246del p.F82Lfs*14 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- ADGRV1 | c.13562A>G p.N4521S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); called by mutect2, varscan2
- ADIRF | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- AFTPH | c.1241del p.N414Mfs*9 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- AGBL2 | c.2393del p.N798Tfs*10 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- AGBL3 | c.2050A>G p.N684D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2
- AKAP4 | c.277-2A>G p.X93_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- AKT3 | c.1354del p.Y452Mfs*54 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- AL592490.1 | c.239T>A p.V80E | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- AMY2B | c.1312A>G p.N438D | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD52 | c.549A>G p.L183= | Splice Region (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- APCDD1L | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- APOB | c.12689A>G p.Q4230R | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APOBR | c.1210G>A p.G404R (on ENST00000431282; = p.G413R on NM_018690.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- AREG | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP42 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ARHGEF11 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ASH1L | c.2533del p.R845Gfs*3 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- ATAD5 | c.1114_1116del p.V372del | In Frame Del (DEL) | VAF 10/56 reads (18%) | called by pindel, varscan2
- ATF7IP | c.1654del p.S552Lfs*32 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ATP10B | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ATP2A2 | c.385del p.V129Cfs*17 | Frame Shift Del (DEL) | VAF 33/214 reads (15%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.453+2T>C p.X151_splice | Splice Site (SNP) | VAF 41/252 reads (16%) | called by muse, mutect2, varscan2
- ATP6V0B | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- ATXN2L | c.2419C>A p.H807N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | called by mutect2, pindel, varscan2
- AVPR1A | c.1053del p.F351Lfs*19 | Frame Shift Del (DEL) | VAF 33/175 reads (19%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.2662dup p.H888Pfs*186 | Frame Shift Ins (INS) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- BARX2 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BAZ1B | c.3846G>A p.L1282= | Splice Region (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- BCL2A1 | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- BIRC6 | c.13922del p.P4641Lfs*3 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
- BMP1 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | called by muse, varscan2
- BMP6 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMPR2 | c.1338del p.F446Lfs*28 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | called by mutect2, pindel, varscan2
- BTG3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- BTN3A3 | c.832dup p.I278Nfs*54 | Frame Shift Ins (INS) | VAF 30/174 reads (17%) | called by mutect2, pindel, varscan2
- C10orf71 | c.3131del p.P1044Lfs*70 | Frame Shift Del (DEL) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- C12orf40 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- C17orf107 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- C1QTNF8 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C2CD4D | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C2orf16 | c.4015del p.R1339Dfs*19 | Frame Shift Del (DEL) | VAF 33/178 reads (19%) | called by mutect2, pindel, varscan2
- CALHM5 | c.738del p.F246Lfs*75 | Frame Shift Del (DEL) | VAF 33/214 reads (15%) | called by mutect2, pindel, varscan2
- CARS1 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP6 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 52/318 reads (16%) | called by mutect2, pindel, varscan2
- CASZ1 | c.2063A>G p.H688R | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CATSPERB | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CBARP | c.1117del p.Q373Rfs*34 (on ENST00000382477; = p.Q353Rfs*37 on NM_152769.3) | Frame Shift Del (DEL) | VAF 16/139 reads (12%) | called by mutect2, pindel, varscan2
- CBLB | c.2816T>C p.L939P | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC197 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC85A | c.1532del p.T511Nfs*91 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- CCR7 | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDC42BPB | c.4943A>G p.E1648G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDCA8 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- CDH12 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- CDH9 | c.1740C>A p.S580R | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDON | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERS3 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD1 | c.1094del p.N365Mfs*26 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CHD4 | c.2796del p.K932Nfs*28 (on ENST00000357008 / NM_001363606.2; = p.K945Nfs*28 on NM_001273.5) | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- CHL1 | c.229del p.Y77Ifs*7 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by pindel, varscan2
- CHL1 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, varscan2
- CHST12 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- CIDEC | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 85/453 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN2 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 70/380 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CLEC12B | c.331T>A p.S111T | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CLGN | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CLMP | c.54dup p.T19Dfs*4 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CMA1 | c.625T>C p.C209R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CMYA5 | c.1460del p.N487Tfs*13 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- CNNM1 | c.1306del p.L436Wfs*100 | Frame Shift Del (DEL) | VAF 63/296 reads (21%) | called by mutect2, pindel, varscan2
- COL10A1 | c.1826A>G p.H609R | Missense Mutation (SNP) | VAF 70/445 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- COL10A1 | c.1403A>G p.D468G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- COL13A1 | c.1154G>T p.G385V (on ENST00000398978 / NM_001130103.2; = p.G328V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL5A1 | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL5A1 | c.4706del p.P1569Rfs*50 | Frame Shift Del (DEL) | VAF 33/144 reads (23%) | called by mutect2, pindel, varscan2
- COMP | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- CSF3 | c.97del p.L33Wfs*16 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10143dup p.G3382Rfs*15 (on ENST00000297405 / NM_001363185.1; = p.G3213Rfs*15 on NM_052900.3) | Frame Shift Ins (INS) | VAF 22/119 reads (18%) | called by mutect2, pindel, varscan2
- CSNK2A3 | c.427_428insTA p.A143Vfs*22 | Frame Shift Ins (INS) | VAF 43/252 reads (17%) | called by mutect2, pindel, varscan2
- CXXC1 | c.1934C>A p.P645H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CYP3A7-CYP3A51P | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- DBX1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DCAF1 | c.2976dup p.Q993Tfs*21 | Frame Shift Ins (INS) | VAF 24/140 reads (17%) | called by mutect2, varscan2
- DCHS1 | c.3646G>T p.G1216* | Nonsense Mutation (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- DDX17 | c.1215-2A>G p.X405_splice | Splice Site (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- DDX19A | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DIRAS3 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DLL3 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DMBT1 | c.7408C>T p.R2470C (on ENST00000338354 / NM_001377530.1; = p.R1713C on NM_004406.3) | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH2 | c.12703C>A p.H4235N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- DNAH8 | c.8341T>C p.F2781L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DOCK2 | c.1843+2T>G p.X615_splice | Splice Site (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- DPYSL3 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DST | c.1169C>T p.A390V (on ENST00000361203 / NM_001374722.1; = p.A64V on NM_001723.6) | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUSP1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- DVL1 | c.986+1del p.X329_splice | Splice Site (DEL) | VAF 39/177 reads (22%) | called by mutect2, pindel, varscan2
- DYNC2I1 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DZIP1L | c.817T>A p.L273I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB5 | c.2000_2001del p.I667Rfs*10 | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel, varscan2
- EFNA2 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF5B | c.3459del p.G1154Dfs*6 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- ENOX1 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, varscan2
- EPG5 | c.5704del p.Y1902Ifs*26 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | called by mutect2, pindel, varscan2
- EPHA10 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EPHA4 | c.541T>C p.F181L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- EPN1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ERBB4 | c.3884T>C p.V1295A | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ESCO1 | c.55del p.S19Vfs*17 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- ETS2 | c.127_128del p.L43Kfs*2 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by pindel, varscan2
- FAM204A | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAM221A | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- FAM83H | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 89/463 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FGFR4 | c.1703del p.P568Qfs*53 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | called by mutect2, pindel, varscan2
825 further variants in this file (293 protein-altering or splice-affecting, 319 silent, 213 other) are not listed here.
